Gene-level copy-number profile of tumor specimen TCGA-XF-AAMG-01A from TCGA case TCGA-XF-AAMG, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 49.3 years (18,021 days).
Specimen TCGA-XF-AAMG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.e9f77971-e64d-48d1-acac-19ce7338bdc6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-AAMG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/92e95bae-04fd-4365-883b-06633026a0b8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 1,084; copy number 2: 5,304; copy number 3: 16,413; copy number 4: 14,167; copy number 5: 11,905; copy number 6: 5,570; copy number 7: 2,282; copy number 8: 751; copy number 9: 1,248; copy number 10: 250; copy number 11: 142; copy number 12: 484; copy number 13: 39; copy number 16: 7; copy number 17: 21; copy number 19: 11; copy number 21: 7; copy number 23: 34; copy number 27: 4; copy number 28: 17; copy number 33: 15; copy number 41: 3; copy number 42: 8; copy number 44: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-AAMG-01A-11D-A42D-01): tumor purity 0.75, ploidy 4.16, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:122,476,958–122,527,296, 4 genes: OR1J1, OR1J2, OR1J4, OR1N1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,334 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:98,660,388–99,766,635, 11 genes, copy number 7 (within-gene range 4–7): AC095031.1, SNX7, PLPPR5, AL445433.2, AL445433.1, PLPPR4, AL365220.1, LINC01708, PALMD, HMGB3P10, FRRS1.
- chr1:111,648,291–111,998,842, 10 genes, copy number 8 (within-gene range 4–8): KRT18P57, RNU6-151P, INKA2, INKA2-AS1, AL049557.1, DDX20, KCND3, KCND3-IT1, KCND3-AS1, LINC01750.
- chr1:119,140,391–166,797,183, 1,010 genes, copy number 7–27 (broad region; genes not listed).
- chr2:12,411,398–28,664,540, 281 genes, copy number 7–10 (broad region; genes not listed).
- chr2:45,569,199–45,569,492, 1 gene, copy number 7: RN7SL414P.
- chr2:75,154,366–77,593,319, 32 genes, copy number 7 (within-gene range 6–7): AC007681.1, GAPDHP57, EVA1A, AC007099.2, AC007099.3, AC007099.1, AC005034.1, U3, MRPL19, SUPT4H1P1, GCFC2, AC005034.3, AC005034.5, AC005034.2, AC005034.6, AC005034.4, AC110614.1, SUCLA2P2, AC073091.1, AC073091.2, PNPP1, USP21P2, RN7SKP203, RN7SKP164, AC068616.2, AC068616.3, AC068616.1, LRRTM4, RNA5SP98, AC079117.1, LRRTM4-AS1, AC013716.1.
- chr2:78,597,911–79,028,505, 5 genes, copy number 8: AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G.
- chr2:86,440,647–95,668,727, 249 genes, copy number 7 (broad region; genes not listed).
- chr2:99,545,419–103,623,830, 66 genes, copy number 9–17 (within-gene range 6–17) (broad region; genes not listed).
- chr3:7,606,890–10,243,745, 63 genes, copy number 8–16 (within-gene range 2–16) (broad region; genes not listed).
- chr3:11,137,093–15,971,253, 107 genes, copy number 9–19 (within-gene range 2–19) (broad region; genes not listed).
- chr3:34,692,820–39,287,920, 85 genes, copy number 7–41 (broad region; genes not listed).
- chr3:77,316,752–77,571,881, 2 genes, copy number 7: VDAC1P7, AC133040.1.
- chr4:46,243,548–49,062,081, 39 genes, copy number 8 (within-gene range 6–8): GABRA2, AC095060.1, RNU6-412P, RAC1P2, COX7B2, GABRA4, GABRB1, AC107398.3, COMMD8, AC107398.4, AC107398.5, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1, AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4.
- chr4:53,986,587–55,373,100, 30 genes, copy number 9–12 (within-gene range 3–12): RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8.
- chr4:138,309,613–138,663,403, 3 genes, copy number 7 (within-gene range 5–7): LINC00499, LINC00500, AC105416.1.
- chr5:39,892,138–50,846,519, 99 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr6:19,143,695–31,959,038, 560 genes, copy number 10–44 (broad region; genes not listed).
- chr6:60,789,805–66,728,904, 40 genes, copy number 7 (within-gene range 4–7): AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P.
- chr6:157,381,133–158,099,176, 11 genes, copy number 8 (within-gene range 5–8): ZDHHC14, MIR3692, SNX9, AL391863.2, AL391863.1, SNX9-AS1, HSPE1P26, RNU6-786P, SYNJ2, AL139330.1, SYNJ2-IT1.
- chr6:166,858,094–166,957,191, 3 genes, copy number 8: AL159163.1, RPS6KA2-AS1, RNASET2.
- chr7:2,558,972–8,752,961, 132 genes, copy number 7 (broad region; genes not listed).
- chr7:11,820,317–19,578,606, 81 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:33,109,557–65,959,563, 638 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr8:61,057,158–106,272,902, 732 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr8:109,470,131–113,493,281, 32 genes, copy number 7 (within-gene range 2–7): MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1.
- chr8:127,289,817–132,111,159, 58 genes, copy number 9: CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1.
- chr10:7,703,316–10,257,466, 27 genes, copy number 7: ITIH2, KIN, ATP5F1C, TAF3, AL353754.1, GATA3, GATA3-AS1, AL390294.1, PRPF38AP1, LINC00708, AL390835.1, AC025946.1, AC025946.2, KRT8P37, CHCHD3P1, RNA5SP299, AL355333.1, LINC02676, AC044784.1, LINC00709, AL138773.1, HSP90AB7P, LINC02663, LINC02670, ELOCP3, Y_RNA, CUX2P1.
- chr11:22,261,209–24,456,010, 25 genes, copy number 8: AC107886.1, AC104009.1, SLC17A6, AC040936.1, LINC01495, AC055878.1, FANCF, GAS2, RNA5SP338, SVIP, AC006299.1, CCDC179, LINC02718, AC100767.2, WIZP1, MIR8054, AC100767.1, THAP12P4, AC068472.1, LINC02726, AC100768.1, RNU6-783P, AC099842.1, LINC02686, Y_RNA.
- chr11:26,559,032–29,989,328, 34 genes, copy number 9–11 (within-gene range 6–11): MUC15, SLC5A12, FIBIN, BBOX1, BBOX1-AS1, CCDC34, LGR4, LGR4-AS1, AC100771.1, LIN7C, BDNF-AS, MIR8087, RNA5SP339, AC104563.1, LINC00678, BDNF, AC103796.1, CBX3P1, HSP90AA2P, AC090159.1, KIF18A, MIR610, METTL15, ATP5MGP8, RN7SKP158, AC104978.1, MIR8068, AC013714.1, LINC02758, LINC02742, OR2BH1P, AC090791.1, AC110056.1, LINC02755.
- chr11:29,482,807–38,014,141, 134 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr11:84,720,826–88,359,684, 73 genes, copy number 11 (broad region; genes not listed).
- chr11:98,938,912–98,945,079, 1 gene, copy number 13: AP002428.1.
- chr11:99,120,176–99,120,490, 1 gene, copy number 13: RN7SKP53.
- chr11:106,465,985–108,593,768, 30 genes, copy number 7 (within-gene range 3–7): AP003173.1, GUCY1A2, AP001282.2, AP001282.1, ASS1P13, AP000766.1, CWF19L2, SMARCE1P1, ALKBH8, AP001823.1, ELMOD1, AP000889.2, AP000889.1, SLN, AP002353.1, SLC35F2, AP001024.1, RAB39A, AP003307.1, CUL5, Y_RNA, AP002433.1, ACAT1, AP002433.2, NPAT, ATM, Y_RNA, C11orf65, POGLUT3, EXPH5.
- chr11:110,355,130–111,879,425, 36 genes, copy number 7 (within-gene range 3–7): LINC02732, FDX1, ARHGAP20, HNRNPA1P60, AP002963.1, AP003973.4, RNA5SP350, AP003973.2, LINC02550, AP003973.3, RPS17P15, AP003973.1, C11orf53, COLCA1, COLCA2, AP002448.1, MIR4491, POU2AF1, RNU2-60P, AP002008.3, AP002008.2, BTG4, AP002008.4, MIR34B, MIR34C, AP002008.1, HOATZ, LAYN, SIK2, AP000925.1, RN7SKP273, PPP2R1B, AP001781.1, ALG9, AP001781.2, ALG9-IT1.
- chr14:83,750,384–84,740,052, 8 genes, copy number 8: RNU6ATAC28P, AL161713.1, LINC02305, AL356807.1, MTND4P33, MTND5P35, MTCYBP27, RNU6-976P.
- chr15:23,912,411–28,099,315, 144 genes, copy number 7–11 (broad region; genes not listed).
- chr16:8,537,605–10,943,021, 63 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,067. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
